Somatic mutation profile of tumor specimen TCGA-VQ-A92D-01A (aliquot TCGA-VQ-A92D-01A-11D-A410-08) from TCGA case TCGA-VQ-A92D, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.3 years (24,595 days).
Specimen TCGA-VQ-A92D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17f0c9b1-b429-48e4-8d66-33af940d5191.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A92D-10A (Blood Derived Normal), aliquot TCGA-VQ-A92D-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2363dbc1-5d2a-41f0-b89f-2776a861e1e9

The open-access MAF lists 143 somatic variants for this specimen: 100 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 39, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 2, 3'UTR 2, In Frame Del 2, Splice Region 2, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50514372; called by muse, mutect2
- AQP8 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99563723; called by muse, mutect2, varscan2
- ARID5B | c.1558A>G p.T520A | Missense Mutation (SNP) | VAF 72/118 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99689054; called by muse, mutect2, varscan2
- ARID5B | c.2842C>G p.R948G | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.402); catalogued as COSV54418629, COSV99689059; called by muse, mutect2, varscan2
- ARMC3 | c.504_506del p.K168del | In Frame Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs1341061682; called by pindel, varscan2
- BRINP3 | c.1836A>C p.L612F | Missense Mutation (SNP) | VAF 143/292 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV100818378; called by muse, mutect2, varscan2
- C2CD3 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as rs755669837, COSV58095409; called by muse, mutect2, varscan2
- CABCOCO1 | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 26/153 reads (17%) | catalogued as COSV100357736; called by muse, mutect2, varscan2
- CACNA1E | c.5702G>A p.R1901H | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs747480727, COSV100701293; called by muse, mutect2, varscan2
- CASC3 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 42/800 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs374144661; called by muse, mutect2
- CCDC85A | c.1138G>T p.G380* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV101339389; called by muse, mutect2, varscan2
- CFAP251 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs201510168, COSV99945560; called by muse, mutect2, varscan2
- CKAP5 | c.3959A>G p.Y1320C | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776238591, COSV100370429; called by muse, mutect2, varscan2
- COG6 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs780630711, COSV62995228; called by muse, mutect2, varscan2
- CR2 | c.2056C>G p.Q686E | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.559); catalogued as COSV100889534; called by muse, mutect2, varscan2
- DNAH11 | c.5559C>A p.F1853L | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100177304; called by muse, mutect2, varscan2
- DPY19L3 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100639108; called by muse, mutect2
- DUSP9 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs781935257, COSV100720066; called by muse, mutect2, varscan2
- EFCAB3 | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 31/258 reads (12%) | catalogued as rs1166002422, COSV100540039; called by muse, mutect2, varscan2
- EOMES | c.1318-1G>A p.X440_splice | Splice Site (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99841715; called by muse, mutect2, varscan2
- EPHB2 | c.931A>G p.R311G | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101006766; called by muse, mutect2, varscan2
- ERBB3 | c.3040G>T p.D1014Y | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.177); catalogued as COSV99915838; called by muse, varscan2
- ERICH1 | c.429A>C p.L143F | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100032194; called by muse, mutect2, varscan2
- FAM193A | c.2399G>A p.G800D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453183939, COSV100218574; called by muse, mutect2, varscan2
- FGF21 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as COSV99711371; called by muse, mutect2
- FGF9 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs765041263, COSV101210939, COSV66644065; called by muse, mutect2, varscan2
- GDA | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.25); catalogued as COSV52996994; called by muse, mutect2, varscan2
- GLRA4 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV65455330; called by muse, mutect2, varscan2
- H3C11 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV58900852; called by muse, mutect2, varscan2
- ICE1 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99663818; called by muse, mutect2, varscan2
- INPP4B | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99523065; called by muse, mutect2, varscan2
- KATNIP | c.1863G>C p.Q621H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV55195286, COSV99849899; called by muse, mutect2, varscan2
- KCNK9 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs754394784, COSV100270392; called by muse, mutect2, varscan2
- KIF18B | c.467A>G p.Q156R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV100191784; called by muse, mutect2, varscan2
- KMT5A | c.554A>C p.Y185S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV100389377; called by muse, mutect2, varscan2
- LAMC2 | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99917051; called by muse, mutect2, varscan2
- LCP1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549696; called by muse, mutect2, varscan2
- LRP4 | c.2195G>T p.S732I | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV101066249; called by muse, mutect2, varscan2
- MAD1L1 | c.500C>G p.S167W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781671971, COSV99765160; called by muse, varscan2
- MAST1 | c.2487del p.A830Rfs*69 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs1181075624; called by mutect2, pindel, varscan2
- MED12L | c.5975C>T p.P1992L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs766967153, COSV56379954; called by muse, mutect2, varscan2
- MME | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV100852258; called by muse, mutect2, varscan2
- MUC16 | c.15803C>T p.T5268M | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); catalogued as rs781661825, COSV67493668; called by muse, mutect2, varscan2
- MYO1C | c.823G>C p.V275L (on ENST00000648651 / NM_001080779.2; = p.V240L on NM_033375.5) | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV100704246; called by muse, mutect2, varscan2
- N4BP2 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788217; called by muse, mutect2, varscan2
- NOCT | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV99763737; called by muse, mutect2
- NPAS4 | c.228C>A p.D76E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.085); catalogued as COSV100214795; called by muse, mutect2, varscan2
- NRG3 | c.954G>T p.R318= | Splice Region (SNP) | VAF 14/73 reads (19%) | catalogued as COSV64543119; called by muse, mutect2, varscan2
- NUP98 | c.4259C>T p.S1420F (on ENST00000359171 / NM_001365126.1; = p.S1403F on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100261539; called by muse, mutect2, varscan2
- OR4C15 | c.342C>A p.F114L (on ENST00000314644; = p.F60L on NM_001001920.2) | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV100115384, COSV58953348; called by muse, mutect2, varscan2
- PAQR9 | c.629G>C p.R210P | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.157); catalogued as COSV100503692, COSV61418052; called by muse, mutect2, varscan2
- PCDHA8 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.214); catalogued as COSV65334962; called by muse, mutect2, varscan2
- PCF11 | c.3251A>T p.Q1084L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.932); catalogued as COSV100017818; called by muse, mutect2, varscan2
- PDZD2 | c.4526C>A p.P1509H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223772; called by muse, mutect2, varscan2
- PLCE1 | c.4012G>A p.G1338R | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.251); catalogued as COSV99593587; called by muse, mutect2, varscan2
- PLK2 | c.1222A>C p.T408P | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV99955807; called by muse, mutect2, varscan2
- PLPPR1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV100883041; called by muse, mutect2, varscan2
- PLTP | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as rs781771799, COSV99509657; called by muse, mutect2, varscan2
- PRKAA2 | c.1088T>C p.L363P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100982752; called by muse, mutect2, varscan2
- PRUNE2 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs543743813, COSV65040618; called by muse, mutect2, varscan2
- RANBP17 | c.1611G>C p.L537F | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV101206090; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as COSV99216706; called by muse, mutect2, varscan2
- RFPL3 | c.467G>A p.R156Q (on ENST00000249007 / NM_001098535.1; = p.R127Q on NM_006604.2) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.517); catalogued as rs750838543, COSV99966916; called by muse, mutect2, varscan2
- RNF216 | c.815G>A p.W272* (on ENST00000425013 / NM_207116.3; = p.W329* on NM_207111.4) | Nonsense Mutation (SNP) | VAF 13/266 reads (5%) | catalogued as COSV101111265; called by muse, mutect2
- RPGRIP1 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs759678050, COSV52857734; called by muse, mutect2, varscan2
- SCLY | c.386A>C p.K129T (on ENST00000651534; = p.K121T on NM_016510.7) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV99615315; called by muse, mutect2, varscan2
- SDK1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV67381874; called by muse, mutect2, varscan2
- SGIP1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99390540; called by muse, mutect2, varscan2
- SLC17A4 | c.490G>C p.A164P | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV64955953; called by muse, mutect2, varscan2
- SLC45A3 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as rs774087128, COSV100901069, COSV100901331; called by muse, mutect2, varscan2
- SLITRK1 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV100999790; called by muse, mutect2, varscan2
- SMTN | c.2469C>A p.N823K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1194973353, COSV100293977; called by muse, mutect2, varscan2
- SPAG17 | c.4000G>T p.D1334Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100307983; called by muse, mutect2, varscan2
- SPHKAP | c.4256G>A p.R1419Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs2396519, COSV60893682; called by muse, mutect2
- SUSD5 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100534930; called by muse, mutect2, varscan2
- SV2B | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1411373759, COSV100370407; called by muse, mutect2, varscan2
- SYCP1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65701291; called by muse, mutect2, varscan2
- TCHH | c.5512C>T p.R1838W | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.358); catalogued as rs1312593306, COSV100914903; called by muse, mutect2, varscan2
- TEX55 | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs147064598; called by muse, varscan2
- TGIF2LY | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs367841917, COSV100339616; called by muse, mutect2, varscan2
- THAP2 | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100350345; called by muse, mutect2, varscan2
- TMEM132A | c.2198C>T p.A733V (on ENST00000453848 / NM_178031.3; = p.A734V on NM_017870.4) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99134011; called by muse, mutect2, varscan2
- TNR | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as rs776846663, COSV54867827; called by muse, mutect2, varscan2
- TOMM40 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV99374777; called by muse, mutect2, varscan2
- TRABD2A | c.1085G>A p.G362E (on ENST00000409520 / NM_001277053.2; = p.G313E on NM_001080824.3) | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770941195, COSV99404919; called by muse, mutect2, varscan2
- TRIO | c.5599G>A p.V1867M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs774835487, COSV60080902; called by muse, mutect2, varscan2
- TRPM4 | c.1263+1G>A p.X421_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as rs1321828986, COSV99419044; called by muse, mutect2, varscan2
- TYROBP | c.228G>A p.E76= | Splice Region (SNP) | VAF 13/56 reads (23%) | catalogued as rs545730787, COSV99385504; called by muse, mutect2, varscan2
- USH1G | c.887_889del p.E296del | In Frame Del (DEL) | VAF 17/77 reads (22%) | catalogued as rs769227044; called by mutect2, pindel, varscan2
- VWA3A | c.3266T>C p.L1089S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1311004165, COSV100240633; called by muse, mutect2, varscan2
- ZNF365 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV101237939, COSV101237962; called by muse, mutect2, varscan2
- ZNF883 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs116612685; called by muse, mutect2, varscan2
- ZSCAN22 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1193147588, COSV61639434; called by muse, mutect2, varscan2
- CTU2 | c.762_774del p.R255Tfs*5 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- GSE1 | c.1676_1682del p.D559Gfs*10 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by mutect2, pindel*, varscan2*
- IGHG3 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- KBTBD4 | c.1235_1236del p.V412Efs*17 | Frame Shift Del (DEL) | VAF 24/137 reads (18%) | called by pindel, varscan2
- SPDL1 | c.331del p.T111Lfs*3 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- SRRM2 | c.6554_6555del p.L2185Hfs*73 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- SRSF1 | c.712dup p.S238Ffs*5 | Frame Shift Ins (INS) | VAF 44/135 reads (33%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.114G>A p.P38= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV100710305; called by muse, mutect2, varscan2
- AGAP4 | c.273G>A p.Q91= | Silent (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- AL031777.2 | c.330C>T p.P110= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs749812440, COSV100587095; called by muse, mutect2, varscan2
- ATG13 | c.816G>A p.Q272= | Silent (SNP) | VAF 34/389 reads (9%) | catalogued as COSV100365482, COSV100365508; called by muse, mutect2
- ATP10D | c.3453C>T p.F1151= | Silent (SNP) | VAF 67/205 reads (33%) | catalogued as COSV99905159; called by muse, mutect2, varscan2
- ATP7B | c.1392G>T p.G464= | Silent (SNP) | VAF 36/254 reads (14%) | catalogued as COSV54435262, COSV99666064; called by muse, mutect2, varscan2
- BRDT | c.2670A>G p.K890= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100746137; called by muse, mutect2, varscan2
- C1orf159 | c.654G>A p.L218= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1442900998, COSV99618176; called by muse, mutect2, varscan2
- CCT5 | c.1083G>A p.E361= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV99725121; called by muse, mutect2
- CENPV | c.423C>T p.G141= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100233430; called by muse, mutect2, varscan2
- COL1A2 | c.1977A>G p.E659= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs995888530, COSV99798659; called by muse, mutect2, varscan2
- CYLD | c.888A>G p.L296= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs781643645, COSV61098163; called by muse, varscan2
- CYP3A7-CYP3A51P | c.1560C>T p.H520= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs1478912086; called by muse, mutect2, varscan2
- DHRS9 | c.330C>T p.I110= | Silent (SNP) | VAF 32/245 reads (13%) | catalogued as COSV100513326; called by muse, mutect2, varscan2
- DNAH9 | c.12783G>C p.R4261= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99304226; called by muse, mutect2, varscan2
- DNAI4 | c.483C>T p.S161= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs1408609761, COSV100925199, COSV64018462; called by muse, mutect2, varscan2
- FAP | c.1254C>T p.Y418= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs763694305, COSV99501733; called by muse, mutect2, varscan2
- FN1 | c.3741T>G p.V1247= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV100116128; called by muse, mutect2, varscan2
- FOXN4 | c.1155C>T p.H385= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs562273482, COSV54499136; called by muse, mutect2, varscan2
- GLMP | c.321C>T p.G107= | Silent (SNP) | VAF 53/277 reads (19%) | catalogued as COSV99827752; called by muse, mutect2, varscan2
- HSD11B1 | c.375T>G p.S125= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV99807902; called by muse, mutect2, varscan2
- JRK | c.162C>T p.D54= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101401033; called by muse, mutect2, varscan2
- KIFC1 | c.1605A>T p.S535= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV100995980; called by muse, mutect2, varscan2
- KLF12 | c.198G>A p.P66= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as rs750790792, COSV100888413; called by muse, mutect2, varscan2
- LAMA5 | c.9417C>T p.N3139= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs974592009, COSV99438138; called by muse, mutect2, varscan2
- LCNL1 | c.48C>T p.D16= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV99811705; called by muse, mutect2, varscan2
- MLLT6 | c.2061C>T p.P687= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- MYB | c.1377C>T p.I459= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs1465967713, COSV100214554; called by muse, mutect2, varscan2
- MYH8 | c.18C>T p.D6= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs757323240, COSV101238208; called by muse, mutect2, varscan2
- MYO19 | c.2283G>A p.L761= (on ENST00000614623 / NM_001163735.1; = p.L561= on NM_025109.5) | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- NLRP6 | c.2529G>A p.L843= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1460068702, COSV100380937; called by muse, mutect2, varscan2
- OR2V2 | c.102G>A p.A34= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as rs201192992, COSV100080014, COSV60316805; called by muse, mutect2, varscan2
- PRX | c.1341T>A p.A447= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99397479; called by muse, mutect2, varscan2
- RELL1 | c.552C>T p.G184= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs772779656, COSV58450072; called by muse, mutect2, varscan2
- RIMS2 | c.1656G>A p.T552= (on ENST00000666250 / NM_001348490.2; = p.T360= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs759567859, COSV99161239, COSV99169677; called by muse, mutect2, varscan2
- SETDB1 | c.2919C>T p.S973= | Silent (SNP) | VAF 216/294 reads (73%) | catalogued as rs587757597, COSV54987104; called by muse, mutect2, varscan2
- TMX1 | c.354G>A p.R118= | Silent (SNP) | VAF 25/194 reads (13%) | catalogued as COSV100790050; called by muse, mutect2, varscan2
- ZFP28 | c.906A>T p.R302= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV100019268; called by muse, mutect2, varscan2
- ZFYVE1 | c.118C>T p.L40= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100606527; called by muse, mutect2, varscan2
- DST | c.16635+395A>T | Intron (SNP) | VAF 61/123 reads (50%) | catalogued as COSV99751336; called by muse, mutect2, varscan2
- NTAQ1 | c.*2C>G | 3'UTR (SNP) | VAF 22/35 reads (63%) | catalogued as COSV99783518; called by muse, mutect2, varscan2
- SNORD114-14 | n.64T>G | RNA (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- STX17 | c.*3_*19del | 3'UTR (DEL) | VAF 24/67 reads (36%) | called by mutect2, pindel, varscan2
